Gene-level copy-number profile of tumor specimen TCGA-HU-8249-01A from TCGA case TCGA-HU-8249, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 76.7 years (28,012 days).
Specimen TCGA-HU-8249-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.3f6b2e4b-547c-4cad-86f1-e9c5a74e2101.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-8249-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 833 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2cc4c71e-2d8f-4d76-aa4a-76fd939e5e58

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 21; copy number 2: 15,111; copy number 3: 14,069; copy number 4: 18,888; copy number 5: 5,705; copy number 6: 1,926; copy number 7: 978; copy number 8: 1,503; copy number 9: 105; copy number 10: 93; copy number 11: 1,205; copy number 12: 17; copy number 13: 129; copy number 14: 32; copy number 18: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-8249-01A-11D-2338-01): tumor purity 0.76, ploidy 3.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,586 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:37,044,860–37,571,460, 17 genes, copy number 12: COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3.
- chr6:43,506,969–47,832,780, 88 genes, copy number 9 (broad region; genes not listed).
- chr7:38,256,337–38,276,318, 5 genes, copy number 18: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1.
- chr10:31,602,862–32,232,245, 17 genes, copy number 9: AL161935.1, AL161935.3, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13.
- chr12:66,767–43,661,101, 931 genes, copy number 11–13 (broad region; genes not listed).
- chr12:47,841,537–49,060,794, 76 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr12:68,842,197–69,959,097, 26 genes, copy number 13 (within-gene range 7–13): CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr12:69,946,543–69,947,081, 1 gene, copy number 13: AC078922.1.
- chr13:18,467,172–36,742,465, 376 genes, copy number 11 (broad region; genes not listed).
- chr14:22,096,032–22,490,553, 49 genes, copy number 10–14: TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
